Gene-level copy-number profile of tumor specimen TCGA-BR-8483-01A from TCGA case TCGA-BR-8483, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 59.5 years (21,731 days).
Specimen TCGA-BR-8483-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.db9a6fa5-b164-4b85-977c-925d386b0d02.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-8483-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/23372a1f-34d0-4044-beb9-8bd0b7d1bc32

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 594; copy number 2: 23,535; copy number 3: 18,798; copy number 4: 8,254; copy number 5: 1,718; copy number 6: 5,341; copy number 7: 129; copy number 8: 1,329; copy number 9: 22; copy number 13: 3; copy number 28: 14; copy number 40: 34; copy number 47: 32; copy number 49: 5; copy number 51: 1; copy number 64: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-8483-01A-31D-2390-01): tumor purity 0.75, ploidy 3.1, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8,639 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:70,972–93,361,123, 1,647 genes, copy number 6 (broad region; genes not listed).
- chr7:94,022,833–159,233,377, 1,352 genes, copy number 6 (broad region; genes not listed).
- chr8:737,628–1,708,476, 1 gene, copy number 5 (within-gene range 2–5): DLGAP2.
- chr8:1,246,789–49,229,174, 988 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:61,785,047–113,436,939, 783 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr8:114,791,653–129,683,770, 193 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr8:129,685,401–145,066,685, 310 genes, copy number 6 (broad region; genes not listed).
- chr10:44,712–38,783,108, 675 genes, copy number 5 (broad region; genes not listed).
- chr10:50,305,586–50,625,163, 1 gene, copy number 6 (within-gene range 3–6): SGMS1.
- chr10:50,472,814–52,298,423, 22 genes, copy number 6 (within-gene range 2–6): AL117341.1, RNU7-107P, SGMS1-AS1, SHQ1P1, BEND3P1, NUTM2HP, AL589794.1, CTSLP4, PGGT1BP1, AL589794.2, ASAH2B, A1CF, AL512366.1, CCDC58P2, AL731537.2, PRKG1, AL731537.1, AC022537.1, MIR605, AC069079.1, RSU1P3, CSTF2T.
- chr13:18,467,172–64,076,044, 799 genes, copy number 6 (broad region; genes not listed).
- chr13:86,402,982–91,131,407, 45 genes, copy number 5: AL445207.1, TXNL1P1, LINC00430, UBBP5, LIN28AP2, AL360267.2, AL360267.1, MIR4500HG, AL355578.1, MIR4500, SLITRK5, AL445647.2, LINC00397, AL445647.1, TET1P1, LINC00373, RPL29P29, AL355677.1, LINC00433, AL445984.2, AL445984.1, LINC00560, GRPEL2P1, AL162573.1, LINC00440, LINC01047, TRIM60P13, SP3P, LINC02336, LINC01040, LINC00353, RPL7L1P1, AL355821.1, PEX12P1, LINC00559, RNA5SP34, FAR1P1, KRT18P27, MIR622, LINC01049, RNU6-75P, LINC00410, BRK1P2, LINC00380, LINC00379.
- chr17:37,375,985–37,479,725, 5 genes, copy number 49 (within-gene range 3–49): C17orf78, AC243654.3, TADA2A, AC243654.1, AC243654.2.
- chr17:39,667,981–40,100,589, 23 genes, copy number 9–51 (within-gene range 3–51): PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C, GSDMA, PSMD3, AC090844.3, CSF3, MED24, MIR6884, SNORD124, THRA, NR1D1.
- chr17:40,287,879–40,527,002, 17 genes, copy number 13–28: CDC6, RARA, AC080112.4, RARA-AS1, AC080112.3, GJD3, AC080112.1, PPIAP54, RNA5SP441, AC080112.2, TOP2A, Y_RNA, RPL23AP75, IGFBP4, AC018629.1, TNS4, AC004585.1.
- chr17:40,818,117–41,256,364, 43 genes, copy number 47–64: KRT10, TMEM99, AC004231.4, KRT12, KRT20, AC004231.1, KRT23, KRT39, KRT40, KRTAP3-3, KRTAP3-2, KRTAP3-4P, KRTAP3-1, KRTAP1-5, KRTAP1-4, KRTAP1-3, KRTAP1-1, KRTAP2-1, KRTAP2-2, KRTAP2-3, KRTAP2-4, KRTAP2-5P, KRTAP4-7, AC100808.1, KRTAP4-8, KRTAP4-16, KRTAP4-9, KRTAP4-11, KRTAP4-12, KRTAP4-6, KRTAP4-5, KRTAP4-4, KRTAP4-3, KRTAP4-2, KRTAP4-1, KRTAP4-17P, KRTAP9-1, KRTAP9-12P, KRTAP9-2, KRTAP9-3, KRTAP9-8, KRTAP9-4, KRTAP9-9.
- chr17:41,275,659–41,715,969, 34 genes, copy number 40: KRTAP9-7, KRTAP9-10P, KRTAP29-1, KRTAP16-1, KRTAP17-1, TBC1D3P7, AC003958.1, KRT33A, KRT33B, KRT34, KRT31, AC003958.2, KRT41P, KRT37, KRT38, KRT43P, KRT32, RNU2-32P, KRT35, KRT36, KRT13, AC019349.1, KRT15, MIR6510, KRT19, LINC00974, KRT9, KRT14, KRT16, KRT17, KRT42P, AC130686.1, EIF1, GAST.
- chr18:31,622,247–49,599,185, 243 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr20:87,250–64,313,132, 1,458 genes, copy number 7–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 590. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
